Somatic mutation profile of tumor specimen C3N-02947-03 (aliquot CPT0158520011) from CPTAC case C3N-02947, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 51.5 years (18,827 days).
Specimen C3N-02947-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1f77ed2-5aa1-403c-8a6e-a4227dcc7456.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02947-31 (Blood Derived Normal), aliquot CPT0159460002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/580780ec-2f2d-4bac-bc08-3874bfc4e047

The open-access MAF lists 1,199 somatic variants for this specimen: 783 protein-altering or splice-affecting, 272 silent, 144 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 505, Silent 272, Frame Shift Del 167, Intron 74, Frame Shift Ins 35, Nonsense Mutation 32, 3'UTR 26, Splice Region 18, 5'UTR 16, RNA 15, In Frame Del 12, Splice Site 11.

Variants (750 of 1,199; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD1 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs193922098, CM021052, COSV54388375; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CEP290 | c.6869dup p.N2290Kfs*6 | Frame Shift Ins (INS) | VAF 30/140 reads (21%) | catalogued as rs587783017; ClinVar: pathogenic; called by mutect2, varscan2
- CPS1 | c.2339G>A p.R780H | Missense Mutation (SNP) | VAF 72/241 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs758724746, CM071661, COSV51807292, COSV99242450; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FKTN | c.1106del p.F369Sfs*37 | Frame Shift Del (DEL) | VAF 48/195 reads (25%) | catalogued as rs750176716; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- HAX1 | c.430dup p.V144Gfs*5 | Frame Shift Ins (INS) | VAF 42/274 reads (15%) | catalogued as rs770288337; ClinVar: pathogenic; called by mutect2, varscan2
- IQSEC2 | c.854del p.P285Lfs*21 (on ENST00000642864 / NM_001111125.3; = p.P80Lfs*21 on NM_015075.2) | Frame Shift Del (DEL) | VAF 32/159 reads (20%) | catalogued as rs782460038; ClinVar: pathogenic; called by mutect2, pindel
- KMT2B | c.521dup p.T176Dfs*8 | Frame Shift Ins (INS) | VAF 24/102 reads (24%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 56/150 reads (37%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NF1 | c.1683G>A p.W561* | Nonsense Mutation (SNP) | VAF 52/204 reads (25%) | catalogued as rs1135402820, COSV62226314; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PKP2 | c.148_151del p.T50Sfs*61 | Frame Shift Del (DEL) | VAF 39/162 reads (24%) | catalogued as rs397516997; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.491del p.K164Rfs*3 | Frame Shift Del (DEL) | VAF 47/197 reads (24%) | catalogued as rs786204900, COSV64297274; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SCN4A | c.2023C>T p.R675W | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121908556, CM043573, CM043574, COSV71127096; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.379T>C p.S127P | Missense Mutation (SNP) | VAF 11/234 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52667433, COSV52678360, COSV52751962; called by muse, mutect2
- ABTB1 | c.367G>T p.G123W | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51743124; called by muse, mutect2, varscan2
- AC099489.1 | c.4661G>A p.R1554H | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.059); catalogued as rs1344365362; called by muse, mutect2
- AFF4 | c.2447C>T p.A816V | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.685); catalogued as COSV54795056; called by muse, mutect2, varscan2
- AGBL4 | c.1162G>A p.G388S | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.876); catalogued as rs1335487849; called by muse, mutect2, varscan2
- AGO1 | c.1417C>T p.R473W | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.824); catalogued as COSV100940893; called by muse, mutect2, varscan2
- AGO4 | c.871G>A p.G291S | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs938936575, COSV100942730; called by muse, mutect2, varscan2
- AKAP8L | c.1348G>A p.V450M | Missense Mutation (SNP) | VAF 85/362 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.139); catalogued as rs780547911; called by muse, mutect2, varscan2
- AKAP8L | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777700296; called by muse, mutect2, varscan2
- AKAP8L | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.845); catalogued as rs747494504, COSV68474596; called by muse, mutect2
- ALDH1L1 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.315); catalogued as COSV56418821; called by muse, mutect2, varscan2
- AMOT | c.2444G>A p.R815Q (on ENST00000371959 / NM_001113490.1; = p.R406Q on NM_133265.3) | Missense Mutation (SNP) | VAF 80/251 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs752196200, COSV59069415; called by muse, mutect2, varscan2
- AMY2B | c.315G>T p.G105= | Splice Region (SNP) | VAF 20/131 reads (15%) | catalogued as rs1189364425, COSV63714093; called by muse, mutect2, varscan2
- ANKRD26 | c.1110del p.E371Kfs*12 | Frame Shift Del (DEL) | VAF 15/97 reads (15%) | catalogued as rs775948884, COSV65797837; called by mutect2, pindel, varscan2
- ANKRD31 | c.1533del p.G512Vfs*20 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | catalogued as rs1279723268; called by mutect2, varscan2
- ANKRD44 | c.2816del p.N939Ifs*16 | Frame Shift Del (DEL) | VAF 20/101 reads (20%) | catalogued as rs1408961377; called by mutect2, pindel, varscan2
- APLP2 | c.187G>A p.V63M | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.998); catalogued as rs1367860042; called by muse, mutect2
- APOBR | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs751358620, COSV60489411; called by mutect2, varscan2
- APRT | c.521_523del p.F174del | In Frame Del (DEL) | VAF 47/184 reads (26%) | catalogued as rs121912681; called by pindel, varscan2
- AQP7 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs62542746; called by muse, mutect2, varscan2
- AQP8 | c.363del p.M122Cfs*10 | Frame Shift Del (DEL) | VAF 49/207 reads (24%) | catalogued as rs759782104; called by mutect2, pindel, varscan2
- ARHGAP26 | c.1994del p.P665Rfs*135 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | catalogued as rs1298538973; called by mutect2, pindel
- ARHGAP33 | c.2822G>A p.R941H | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as rs755309814, COSV50135707; called by muse, varscan2
- ARHGEF10L | c.2180G>A p.R727H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs770074422; called by muse, mutect2, varscan2
- ARID4A | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100794651; called by muse, mutect2, varscan2
- ARMC4 | c.1790C>T p.S597L | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs532755252, COSV59461058; called by muse, mutect2, varscan2
- ASCC1 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 107/366 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765691174; called by muse, mutect2, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 28/93 reads (30%) | catalogued as rs768611141; called by mutect2, pindel, varscan2
- ATP10A | c.1504C>T p.H502Y | Missense Mutation (SNP) | VAF 75/436 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.818); catalogued as rs150791603, COSV100791098; called by muse, mutect2, varscan2
- ATP10B | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 87/319 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs192248100; called by muse, mutect2, varscan2
- ATP2C2 | c.2519C>T p.T840M | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771963137; called by muse, mutect2, varscan2
- ATPSCKMT | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs559270054, COSV54726807, COSV99725982; called by muse, mutect2
- B4GALNT4 | c.447G>A p.T149= | Splice Region (SNP) | VAF 62/273 reads (23%) | catalogued as rs199948760; called by muse, mutect2, varscan2
- BAG5 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 50/393 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); catalogued as rs1461075781; called by muse, mutect2, varscan2
- BAHCC1 | c.6694C>T p.R2232W | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs782506054; called by muse, mutect2, varscan2
- BAIAP3 | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs150054474; called by muse, mutect2
- BARD1 | c.2251C>T p.R751W | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139785364; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BICD2 | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 124/477 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1454949934; called by muse, mutect2, varscan2
- C1QTNF4 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.967); catalogued as rs1407002241; called by muse, mutect2, varscan2
- C9orf131 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 22/308 reads (7%) | catalogued as rs144687989, COSV56610059; called by muse, mutect2
- C9orf131 | c.3068G>A p.R1023Q | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs144471202; called by muse, mutect2, varscan2
- CABLES1 | c.1329del p.S444Afs*33 (on ENST00000256925 / NM_001100619.2; = p.S179Afs*33 on NM_138375.2) | Frame Shift Del (DEL) | VAF 31/144 reads (22%) | catalogued as COSV99908784; called by mutect2, pindel, varscan2
- CAMSAP2 | c.3682C>T p.R1228C (on ENST00000236925 / NM_001297707.2; = p.R1217C on NM_203459.3) | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749701945, COSV52667116; called by muse, mutect2, varscan2
- CASR | c.2239G>A p.A747T (on ENST00000490131; = p.A824T on NM_000388.4) | Missense Mutation (SNP) | VAF 154/599 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as CM124161, CM983515, COSV56141145; called by muse, mutect2, varscan2
- CASZ1 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 81/235 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); catalogued as rs532992894; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 30/96 reads (31%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC6 | c.50G>A p.S17N | Missense Mutation (SNP) | VAF 83/237 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.171); catalogued as COSV54059121; called by muse, mutect2, varscan2
- CCDC8 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 118/376 reads (31%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.005); catalogued as rs761174942, COSV56773594; called by muse, mutect2, varscan2
- CD59 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 78/273 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745985153; called by muse, mutect2, varscan2
- CD93 | c.838del p.D280Mfs*19 | Frame Shift Del (DEL) | VAF 18/215 reads (8%) | catalogued as rs1276928429, COSV55666935; called by mutect2, pindel
- CDC42EP1 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs61747263; called by muse, mutect2, varscan2
- CDH5 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 109/390 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as rs755175346; called by muse, mutect2, varscan2
- CDK10 | c.962_964del p.S321del (on ENST00000353379 / NM_052988.5; = p.S250del on NM_052987.4) | In Frame Del (DEL) | VAF 15/67 reads (22%) | catalogued as rs776867173; called by mutect2, pindel, varscan2
- CECR2 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52847961; called by muse, mutect2, varscan2
- CELSR3 | c.5706dup p.G1903Rfs*107 | Frame Shift Ins (INS) | VAF 56/227 reads (25%) | catalogued as rs758652861; called by mutect2, varscan2
- CELSR3 | c.3548G>A p.R1183H | Missense Mutation (SNP) | VAF 124/496 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs140341250; called by muse, mutect2, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | catalogued as rs1325731082; called by mutect2, pindel, varscan2
- CHAF1A | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1462007485, COSV56674104; called by muse, mutect2, varscan2
- CHEK1 | c.676del p.T226Hfs*14 | Frame Shift Del (DEL) | VAF 30/115 reads (26%) | catalogued as rs757716680, COSV54024545; called by mutect2, varscan2
- CHRNA1 | c.367del p.I123Ffs*67 (on ENST00000261007 / NM_001039523.3; = p.I98Ffs*67 on NM_000079.4) | Frame Shift Del (DEL) | VAF 85/333 reads (26%) | catalogued as rs753250273; called by mutect2, pindel, varscan2
- CLCN2 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 34/298 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs1232361514; called by muse, mutect2, varscan2
- CLDN18 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99480931; called by muse, mutect2, varscan2
- CLIP2 | c.2285_2287del p.K762del | In Frame Del (DEL) | VAF 80/302 reads (26%) | catalogued as rs1273300405; called by pindel, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 22/94 reads (23%) | catalogued as rs369752219; called by mutect2, varscan2
- CLTCL1 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 79/315 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs200120774, COSV54232890; called by muse, mutect2, varscan2
- CLU | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 101/414 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.207); catalogued as rs753592928, COSV100324413; called by muse, mutect2, varscan2
- CLUH | c.1324del p.D442Tfs*12 (on ENST00000435359; = p.D480Tfs*12 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 24/232 reads (10%) | catalogued as rs752224729; called by mutect2, pindel, varscan2
- CMTM5 | c.377del p.P126Rfs*55 | Frame Shift Del (DEL) | VAF 67/243 reads (28%) | catalogued as rs751921758; called by mutect2, pindel, varscan2
- CNEP1R1 | c.336+14del | Splice Region (DEL) | VAF 44/167 reads (26%) | catalogued as rs1006253245; called by mutect2, pindel, varscan2
- CNOT3 | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 57/251 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV55360681; called by muse, mutect2, varscan2
- CNTNAP5 | c.1220C>T p.T407I | Missense Mutation (SNP) | VAF 120/455 reads (26%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.999); catalogued as COSV70507997; called by muse, mutect2, varscan2
- COL4A3 | c.2591A>G p.Q864R | Missense Mutation (SNP) | VAF 34/390 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV67414831; called by muse, mutect2
- CRACR2B | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 102/343 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs375052201; called by muse, mutect2, varscan2
- CRB2 | c.420C>T p.G140= | Splice Region (SNP) | VAF 65/171 reads (38%) | catalogued as COSV63502146; called by muse, mutect2, varscan2
- CRYM | c.251G>A p.G84D | Missense Mutation (SNP) | VAF 93/394 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.019); catalogued as rs1262100500; called by muse, mutect2, varscan2
- CSMD3 | c.3908C>T p.T1303M (on ENST00000297405 / NM_001363185.1; = p.T1199M on NM_052900.3) | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs761300141, COSV52223234; called by muse, mutect2, varscan2
- CUL9 | c.2941G>A p.V981M | Missense Mutation (SNP) | VAF 53/482 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs374241248; called by muse, mutect2, varscan2
- CWC22 | c.1515A>T p.K505N | Missense Mutation (SNP) | VAF 53/247 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as COSV55427195; called by muse, mutect2, varscan2
- CYLD | c.1360G>A p.V454I | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs200451975; called by muse, mutect2, varscan2
- CYP11B2 | c.1019T>C p.L340P | Missense Mutation (SNP) | VAF 42/556 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100010915; called by muse, mutect2
- CYP27A1 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 82/287 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761927223, COSV51470516; called by muse, mutect2, varscan2
- DAB2 | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 48/500 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs769932133; called by muse, mutect2
- DACT3 | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.208); catalogued as rs774957424; called by muse, mutect2, varscan2
- DAPK3 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs1378923587; called by muse, mutect2, varscan2
- DCANP1 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs778844390; called by muse, mutect2, varscan2
- DDIT4 | c.671C>A p.S224* | Nonsense Mutation (SNP) | VAF 32/147 reads (22%) | catalogued as COSV100259207, COSV56577503; called by muse, mutect2, varscan2
- DDX60 | c.3398del p.L1133Yfs*4 | Frame Shift Del (DEL) | VAF 26/77 reads (34%) | catalogued as rs778036194; called by mutect2, varscan2
- DENND2B | c.1288G>A p.V430I | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs757125041; called by muse, mutect2
- DENND4B | c.22dup p.R8Pfs*20 | Frame Shift Ins (INS) | VAF 12/64 reads (19%) | catalogued as rs755611865; called by mutect2, varscan2
- DHDDS | c.673C>A p.L225M | Missense Mutation (SNP) | VAF 83/412 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.728); catalogued as COSV52577083; called by muse, mutect2, varscan2
- DIP2B | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 38/122 reads (31%) | catalogued as COSV56587654; called by muse, varscan2
- DIPK1A | c.563T>C p.L188S | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1246558039; called by muse, mutect2, varscan2
- DIRAS1 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.48); catalogued as COSV100052954, COSV60216592; called by muse, mutect2, varscan2
- DMRTA1 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.084); catalogued as rs775700148, COSV100364802, COSV57923910; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH1 | c.7198+1G>A p.X2400_splice | Splice Site (SNP) | VAF 30/124 reads (24%) | catalogued as rs367692811; called by muse, mutect2, varscan2
- DNAH12 | c.1941del p.K647Nfs*24 | Frame Shift Del (DEL) | VAF 38/147 reads (26%) | catalogued as COSV61059259; called by mutect2, pindel, varscan2
- DNAH8 | c.1739A>G p.H580R | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs940191116; called by muse, mutect2, varscan2
- DOCK10 | c.1122dup p.D375Rfs*6 | Frame Shift Ins (INS) | VAF 18/80 reads (23%) | catalogued as rs750262341; called by mutect2, varscan2
- DOCK4 | c.5246G>A p.R1749H | Missense Mutation (SNP) | VAF 86/276 reads (31%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.932); catalogued as rs564183702; called by muse, mutect2, varscan2
- DPH2 | c.1267T>C p.W423R | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs776786597; called by muse, mutect2, varscan2
- DPP7 | c.1205del p.G402Vfs*28 | Frame Shift Del (DEL) | VAF 38/122 reads (31%) | catalogued as rs748560644; called by mutect2, pindel, varscan2
- EDN1 | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 67/305 reads (22%) | catalogued as rs202114325; called by muse, mutect2, varscan2
- EDN3 | c.391A>G p.N131D | Missense Mutation (SNP) | VAF 77/297 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs755789488; called by muse, mutect2, varscan2
- ELFN2 | c.1036G>A p.V346M | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as rs1330737691, COSV68743689; called by muse, mutect2, varscan2
- ENSA | c.293C>A p.P98H | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99651272; called by muse, mutect2, varscan2
- EPHA1 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs35719334; called by muse, mutect2, varscan2
- EPHA1 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 128/454 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs140233341; called by muse, mutect2, varscan2
- ERCC2 | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 119/437 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs557601608, COSV67271138; called by muse, mutect2, varscan2
- ERCC4 | c.874C>T p.R292* | Nonsense Mutation (SNP) | VAF 53/165 reads (32%) | catalogued as rs759268826; called by muse, mutect2, varscan2
- ERICH6 | c.662T>C p.L221P | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1286573229; called by muse, mutect2
- ERN1 | c.842+1G>A p.X281_splice | Splice Site (SNP) | VAF 8/102 reads (8%) | catalogued as rs1374944834; called by muse, mutect2
- EVL | c.560del p.P187Hfs*41 (on ENST00000402714 / NM_001330221.2; = p.P189Hfs*41 on NM_016337.3) | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | catalogued as rs746606863; called by mutect2, varscan2
- F11 | c.1811G>A p.R604Q | Missense Mutation (SNP) | VAF 112/473 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs1239471962; called by muse, mutect2, varscan2
- F5 | c.4873G>A p.D1625N | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs914900338, COSV63120310; called by muse, mutect2, varscan2
- FAM13B | c.2346dup p.E783* | Frame Shift Ins (INS) | VAF 36/146 reads (25%) | catalogued as rs1203077575; called by mutect2, varscan2
- FAM20B | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.066); catalogued as COSV55380157; called by muse, mutect2
- FAT1 | c.6899C>T p.T2300M | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs761083769, COSV101499556; called by muse, mutect2, varscan2
- FBXO46 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 62/194 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58348266; called by muse, mutect2, varscan2
- FES | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 88/334 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs748716030; called by muse, mutect2, varscan2
- FHOD3 | c.3959C>T p.S1320L (on ENST00000359247 / NM_001281739.3; = p.S1337L on NM_025135.5) | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV57182975; called by muse, mutect2, varscan2
- FLT4 | c.2293G>A p.V765M | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56122101; called by muse, mutect2, varscan2
- FLYWCH2 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as rs376595971; called by muse, mutect2, varscan2
- FMN1 | c.3936del p.E1313Sfs*25 (on ENST00000616417 / NM_001277313.2; = p.E1090Sfs*25 on NM_001103184.4) | Frame Shift Del (DEL) | VAF 31/138 reads (22%) | catalogued as rs752560237; called by mutect2, pindel, varscan2
- FNDC1 | c.5219C>A p.P1740H | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1193088487; called by muse, mutect2, varscan2
- FNIP2 | c.1743del p.I582Sfs*94 | Frame Shift Del (DEL) | VAF 69/273 reads (25%) | catalogued as COSV52437011; called by mutect2, pindel, varscan2
- FOXN1 | c.1748del p.P583Lfs*5 | Frame Shift Del (DEL) | VAF 39/154 reads (25%) | catalogued as rs1298276474; called by mutect2, pindel, varscan2
- FRS3 | c.163G>A p.V55I | Missense Mutation (SNP) | VAF 128/381 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.199); catalogued as rs200285392, COSV52485134; called by muse, mutect2, varscan2
- FSIP2 | c.3586T>C p.S1196P | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV100554924, COSV104420839; called by muse, mutect2, varscan2
- FSTL4 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142873608; called by muse, mutect2, varscan2
- FUBP1 | c.30del p.S11Lfs*43 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs908264837; called by mutect2, varscan2
- FYB1 | c.972dup p.P325Afs*43 | Frame Shift Ins (INS) | VAF 43/202 reads (21%) | catalogued as rs748874978; called by mutect2, varscan2
- GABRA5 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 74/382 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs776753706, COSV59482014; called by muse, varscan2
- GABRR1 | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.769); catalogued as rs772700915, COSV65619750; called by muse, mutect2, varscan2
- GABRR1 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as rs538977133; called by muse, varscan2
- GAS2L1 | c.1060del p.D354Tfs*34 | Frame Shift Del (DEL) | VAF 25/80 reads (31%) | catalogued as rs1433680093; called by mutect2, pindel, varscan2
- GCNT4 | c.880del p.H294Ifs*14 | Frame Shift Del (DEL) | VAF 32/137 reads (23%) | catalogued as rs768450027; called by mutect2, pindel, varscan2
- GPC2 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.683); catalogued as rs752689029, COSV52786844; called by muse, mutect2
- GPT | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 189/659 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs776157825, COSV52954002; called by muse, mutect2, varscan2
- GRIK3 | c.2566C>T p.R856C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1039838704, COSV66136255; called by muse, mutect2
- GRIK3 | c.2203G>A p.A735T | Missense Mutation (SNP) | VAF 106/387 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs978817918; called by muse, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | catalogued as rs754199513; called by mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 24/89 reads (27%) | catalogued as COSV54945907; called by mutect2, varscan2
- HACE1 | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 128/485 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs770716775; called by muse, mutect2, varscan2
- HAND2 | c.282dup p.P95Afs*248 | Frame Shift Ins (INS) | VAF 30/106 reads (28%) | catalogued as rs752622628; called by mutect2, varscan2
- HEATR5A | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs541257371; called by muse, mutect2, varscan2
- HERC6 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as rs778687408, COSV52030060; called by muse, mutect2, varscan2
- HGS | c.1447del p.A483Rfs*2 | Frame Shift Del (DEL) | VAF 29/110 reads (26%) | catalogued as rs1555699517, COSV100230656; called by mutect2, pindel, varscan2
- HIC2 | c.481del p.R161Afs*113 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs745918762; called by mutect2, pindel
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs767148651; called by mutect2, varscan2
- HPS6 | c.1674del p.N559Mfs*54 | Frame Shift Del (DEL) | VAF 173/594 reads (29%) | catalogued as rs764867254; called by mutect2, varscan2
- HSPA12A | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.629); catalogued as rs201043111; called by muse, mutect2
- HSPA12B | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs146443971; called by muse, mutect2, varscan2
- HSPH1 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as rs1349979623; called by muse, mutect2
- HTR3D | c.26del p.P9Qfs*19 | Frame Shift Del (DEL) | VAF 33/130 reads (25%) | catalogued as rs773798039; called by mutect2, pindel, varscan2
- HUS1B | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57871566; called by muse, mutect2, varscan2
- IDH3B | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 137/596 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66484389; called by muse, mutect2, varscan2
- IFT88 | c.1413+12dup | Splice Region (INS) | VAF 42/116 reads (36%) | catalogued as rs769655324; called by mutect2, varscan2
- IGFN1 | c.2752C>T p.R918W (on ENST00000295591 / NM_001367841.1; = p.R3375W on NM_001164586.2) | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1276928055; called by muse, mutect2, varscan2
- IKZF1 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 83/278 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV58781484, COSV58789880; called by muse, mutect2, varscan2
- INAVA | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV66256953; called by muse, mutect2, varscan2
- INO80E | c.633del p.T212Rfs*3 | Frame Shift Del (DEL) | VAF 30/42 reads (71%) | catalogued as rs759306300, COSV58752155, COSV58752733; called by mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 35/92 reads (38%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- INSYN2A | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 13/243 reads (5%) | catalogued as rs1223237561, COSV54730803; called by muse, mutect2
- INSYN2B | c.632G>A p.S211N | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1246949634, COSV99912553; called by muse, mutect2, varscan2
- IRX2 | c.1154C>T p.T385M | Missense Mutation (SNP) | VAF 12/364 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57410693; called by muse, mutect2
- ISLR2 | c.1610del p.G537Afs*10 | Frame Shift Del (DEL) | VAF 45/159 reads (28%) | catalogued as rs750461351; called by mutect2, pindel, varscan2
- ITSN1 | c.4382G>A p.R1461H | Missense Mutation (SNP) | VAF 68/233 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1357531112, COSV67157140; called by muse, mutect2, varscan2
- JAG1 | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 133/445 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.259); catalogued as rs1436726865, CX122869; called by muse, mutect2, varscan2
- JAKMIP1 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777386141; called by muse, mutect2, varscan2
- KDM6B | c.1537del p.R513Afs*69 | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | catalogued as rs747555402; called by mutect2, varscan2
- KERA | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 11/240 reads (5%) | catalogued as rs1205253713; called by muse, mutect2
- KLC2 | c.91_92del p.L31Afs*15 | Frame Shift Del (DEL) | VAF 79/354 reads (22%) | catalogued as rs1231406020; called by pindel, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | catalogued as rs749194179; called by mutect2, varscan2
- KLRC3 | c.588-1G>T p.X196_splice | Splice Site (SNP) | VAF 21/60 reads (35%) | catalogued as COSV101122932; called by muse, mutect2
- KMT2B | c.5636del p.G1879Vfs*16 | Frame Shift Del (DEL) | VAF 34/169 reads (20%) | catalogued as COSV55868319; called by mutect2, pindel, varscan2
- KRT74 | c.1516C>T p.R506* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as rs537654110, COSV59770745; called by muse, mutect2, varscan2
- KRTAP5-2 | c.261_289del p.C88Lfs*23 | Frame Shift Del (DEL) | VAF 80/261 reads (31%) | catalogued as rs753317529; called by mutect2, varscan2*
- LAMA2 | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 70/286 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1554206054; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMC1 | c.3442G>A p.A1148T | Missense Mutation (SNP) | VAF 65/241 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.825); catalogued as rs370475033; called by muse, mutect2, varscan2
- LBR | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 90/358 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as rs560305402; called by muse, mutect2, varscan2
- LENG8 | c.819C>T p.H273= | Splice Region (SNP) | VAF 55/167 reads (33%) | catalogued as rs904215228; called by muse, mutect2, varscan2
- LINC01804 | n.316G>A | Splice Region (SNP) | VAF 29/159 reads (18%) | catalogued as rs1436273727; called by muse, mutect2, varscan2
- LINGO2 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs750277332; called by muse, mutect2, varscan2
- LIX1L | c.599G>A p.G200D | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as rs1553758032; called by muse, mutect2, varscan2
- LRP3 | c.2177C>A p.P726Q | Missense Mutation (SNP) | VAF 117/356 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.285); catalogued as COSV53504755; called by muse, mutect2, varscan2
- LRP5 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs1019409513, COSV53721437; called by muse, mutect2, varscan2
- LRP5 | c.4488G>A p.P1496= | Splice Region (SNP) | VAF 20/68 reads (29%) | catalogued as rs1565118560; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP6 | c.3277C>T p.R1093W | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752896710, COSV53789294; called by muse, mutect2, varscan2
- LTN1 | c.2100del p.V701Sfs*5 | Frame Shift Del (DEL) | VAF 23/75 reads (31%) | catalogued as rs753955477; called by mutect2, pindel, varscan2
- LZTR1 | c.689A>G p.N230S | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs752439876, COSV53147863; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LZTS1 | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs547948010, COSV56117440; called by muse, mutect2, varscan2
- MAN2B1 | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 33/355 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.429); catalogued as rs370551216; called by muse, mutect2
- MAPRE1 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 65/259 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV65032674; called by muse, mutect2, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | catalogued as rs746267361; called by mutect2, varscan2
- MCEMP1 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 27/82 reads (33%) | catalogued as rs575394812; called by muse, mutect2, varscan2
- MCM3AP | c.2987C>T p.A996V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs778878854; called by muse, mutect2
- MDN1 | c.8073del p.F2691Lfs*7 | Frame Shift Del (DEL) | VAF 32/110 reads (29%) | catalogued as rs35107588; called by mutect2, varscan2
- MED12L | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 52/269 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767172781, COSV56378478; called by muse, mutect2, varscan2
- MED15 | c.2012G>A p.R671Q (on ENST00000263205 / NM_001003891.3; = p.R631Q on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as rs559181543; called by muse, mutect2, varscan2
- MEGF10 | c.1684G>A p.G562R | Missense Mutation (SNP) | VAF 70/231 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768600085, COSV99174844, COSV99175917; called by muse, mutect2, varscan2
- MEGF9 | c.890G>A p.G297D | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs960092769; called by muse, mutect2, varscan2
- MFAP1 | c.750del p.E251Sfs*34 | Frame Shift Del (DEL) | VAF 24/146 reads (16%) | catalogued as rs1567176527; called by mutect2, pindel, varscan2
- MFSD1 | c.1289-2A>G p.X430_splice | Splice Site (SNP) | VAF 61/182 reads (34%) | catalogued as rs755047911; called by muse, mutect2, varscan2
- MICALL2 | c.2257G>A p.A753T | Missense Mutation (SNP) | VAF 96/355 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as rs187391312; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | catalogued as rs762448666; called by mutect2, pindel
- MMP12 | c.205C>T p.H69Y | Missense Mutation (SNP) | VAF 105/410 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as rs1367318471; called by muse, mutect2, varscan2
- MON1A | c.1552G>A p.G518R | Missense Mutation (SNP) | VAF 65/254 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs770602746, COSV56562924; called by muse, mutect2, varscan2
- MSLN | c.1594A>G p.M532V (on ENST00000382862 / NM_013404.4; = p.M524V on NM_005823.6) | Missense Mutation (SNP) | VAF 95/362 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs766806400; called by muse, varscan2
- MSRB3 | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 20/355 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV57590135; called by muse, mutect2
- MTCL1 | c.2069del p.G690Vfs*9 (on ENST00000306329 / NM_001378206.1; = p.G330Vfs*9 on NM_015210.4) | Frame Shift Del (DEL) | VAF 53/206 reads (26%) | catalogued as COSV60404283; called by mutect2, pindel, varscan2
- MTMR9 | c.584del p.N195Mfs*4 | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | catalogued as rs767880823; called by mutect2, varscan2
- MTREX | c.1251del p.K418Rfs*24 | Frame Shift Del (DEL) | VAF 13/61 reads (21%) | catalogued as rs1445650082; called by mutect2, pindel, varscan2
- MTUS2 | c.2549C>T p.A850V | Missense Mutation (SNP) | VAF 59/254 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777823437; called by muse, mutect2, varscan2
- MUC17 | c.12721C>T p.R4241C | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as rs749795865, COSV60301266; called by muse, mutect2, varscan2
- MXRA8 | c.1127A>C p.K376T | Missense Mutation (SNP) | VAF 71/284 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as rs771021474; called by muse, mutect2, varscan2
- MYNN | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.134); catalogued as rs776819666; called by muse, mutect2, varscan2
- MYO16 | c.5144C>T p.T1715M | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs375722670; called by muse, mutect2, varscan2
- MYO7A | c.2501G>A p.R834H | Missense Mutation (SNP) | VAF 90/356 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.578); catalogued as rs569858361; called by muse, mutect2, varscan2
- MYORG | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs755543919, COSV52628883; called by muse, mutect2, varscan2
- NDRG2 | c.1040G>A p.R347H (on ENST00000298687 / NM_001354570.1; = p.R333H on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/242 reads (24%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.997); catalogued as rs750366803; called by muse, mutect2, varscan2
- NEB | c.18803G>A p.R6268H | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs766732299, COSV51437521; called by muse, varscan2
- NECTIN1 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373047519, COSV99872749; called by muse, mutect2, varscan2
- NEK5 | c.94A>G p.I32V | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs199552760; called by muse, mutect2, varscan2
- NEURL1 | c.1270G>A p.V424M | Missense Mutation (SNP) | VAF 66/197 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1340508504; called by muse, mutect2, varscan2
- NF1 | c.499_502del p.C167Qfs*10 | Frame Shift Del (DEL) | VAF 32/129 reads (25%) | catalogued as rs786201874; called by pindel, varscan2
- NFIB | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 63/200 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66620799; called by muse, mutect2, varscan2
- NHS | c.4583C>A p.P1528H | Missense Mutation (SNP) | VAF 78/212 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as rs1064797359; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NIFK | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as rs1324714377; called by muse, mutect2, varscan2
- NINJ1 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.532); catalogued as rs755546683, COSV100966592; called by muse, mutect2, varscan2
- NKAPL | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1021879879, COSV59196888; called by muse, mutect2, varscan2
- NLRP14 | c.643del p.Y215Ifs*10 | Frame Shift Del (DEL) | VAF 46/226 reads (20%) | catalogued as rs767663966; called by mutect2, pindel, varscan2
- NOS1 | c.2027del p.G676Afs*64 | Frame Shift Del (DEL) | VAF 9/104 reads (9%) | catalogued as rs746543323; called by mutect2, pindel
- NOS3 | c.353del p.P118Rfs*7 | Frame Shift Del (DEL) | VAF 26/96 reads (27%) | catalogued as rs1287075410; called by mutect2, pindel, varscan2
- NPBWR2 | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 74/228 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.849); catalogued as rs748833998, COSV100871158; called by muse, mutect2, varscan2
- NPR1 | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs994822671, COSV64141077; called by muse, mutect2, varscan2
- NUDT10 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.417); catalogued as COSV62854476; called by muse, varscan2
- NUMB | c.986C>T p.S329F (on ENST00000355058; = p.S318F on NM_003744.5) | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1182440658, COSV61831745; called by muse, mutect2, varscan2
- OLFML3 | c.795del p.Y266Tfs*3 | Frame Shift Del (DEL) | VAF 9/66 reads (14%) | catalogued as rs753594963; called by mutect2, pindel, varscan2
- OPA3 | c.365T>C p.L122P | Missense Mutation (SNP) | VAF 97/363 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs771753477; called by muse, mutect2, varscan2
- OPLAH | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 64/215 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs1227400999; called by muse, mutect2, varscan2
- OR10H1 | c.388del p.L130Cfs*7 | Frame Shift Del (DEL) | VAF 34/153 reads (22%) | catalogued as rs774838264; called by mutect2, pindel, varscan2
- OR10H2 | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.283); catalogued as rs751844869, COSV59945682; called by muse, mutect2, varscan2
- OR51E2 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 53/267 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs761789724; called by muse, mutect2, varscan2
- OR6Y1 | c.707C>A p.A236D | Missense Mutation (SNP) | VAF 74/292 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV56929484; called by muse, mutect2, varscan2
- OR8D4 | c.529T>C p.Y177H | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139457141; called by muse, mutect2
- P2RY2 | c.703G>A p.G235S | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs201094762; called by muse, mutect2, varscan2
- P4HA2 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 12/338 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.41); catalogued as rs1430322908; called by muse, mutect2
- PANK1 | c.1199dup p.P401Afs*5 (on ENST00000307534 / NM_148977.2; = p.P176Afs*5 on NM_138316.4) | Frame Shift Ins (INS) | VAF 50/246 reads (20%) | catalogued as rs1564621823; called by mutect2, varscan2
- PBX2 | c.130del p.V44Sfs*17 | Frame Shift Del (DEL) | VAF 22/93 reads (24%) | catalogued as rs747720400, COSV66708728; called by mutect2, pindel
- PCDHA6 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 244/871 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); catalogued as COSV65343569; called by muse, mutect2, varscan2
- PCDHA8 | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 152/493 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.082); catalogued as rs1345239073, COSV100969923; called by muse, mutect2, varscan2
- PCDHB16 | c.1267G>A p.V423I | Missense Mutation (SNP) | VAF 71/278 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs781890693, COSV99501902; called by muse, mutect2, varscan2
- PCDHGA2 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.223); catalogued as rs781011056; called by muse, mutect2, varscan2
- PCYOX1L | c.1327C>T p.L443F | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99199267; called by muse, mutect2, varscan2
- PDHX | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 100/262 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as rs141506224; called by muse, mutect2, varscan2
- PDK2 | c.842A>G p.E281G | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs765291523; called by muse, mutect2
- PEG3 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs764907402, COSV55624386; called by muse, mutect2, varscan2
- PFAS | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200676481; called by muse, mutect2, varscan2
- PFKFB4 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 15/81 reads (19%) | PolyPhen benign (0.416); catalogued as rs142378118, COSV51682960; called by muse, mutect2, varscan2
- PHF1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs1481061519; called by muse, mutect2, varscan2
- PHKA2 | c.3336+3A>G | Splice Region (SNP) | VAF 124/441 reads (28%) | catalogued as COSV66054000; called by muse, mutect2, varscan2
- PIANP | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 105/353 reads (30%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.036); catalogued as COSV57708294; called by muse, mutect2, varscan2
- PIGZ | c.1070T>C p.L357P | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV53013105; called by muse, mutect2, varscan2
- PKP4 | c.1862G>A p.R621Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.577); catalogued as rs368077330; called by muse, mutect2
- PLAUR | c.170_172del p.G57del | In Frame Del (DEL) | VAF 38/106 reads (36%) | catalogued as rs1180373617; called by mutect2, pindel, varscan2
- PLCH1 | c.4966G>A p.A1656T (on ENST00000340059 / NM_001130960.2; = p.A1648T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs1399266679; called by muse, mutect2, varscan2
- PLEKHF1 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as COSV71410204; called by muse, mutect2, varscan2
- PLEKHM1 | c.3124del p.R1042Afs*24 | Frame Shift Del (DEL) | VAF 111/484 reads (23%) | catalogued as COSV51818060, COSV51818456; called by mutect2, pindel, varscan2
- PLOD3 | c.1127+6C>T | Splice Region (SNP) | VAF 88/385 reads (23%) | catalogued as rs780052403; called by muse, mutect2, varscan2
- PLXNA1 | c.5498C>T p.A1833V | Missense Mutation (SNP) | VAF 83/321 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as rs564497912, COSV52527133; called by muse, mutect2, varscan2
- PLXNA3 | c.5477C>T p.A1826V | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1018329215, COSV104424235; called by muse, mutect2, varscan2
- PLXNB2 | c.2527C>T p.R843W | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.72); catalogued as COSV63782907; called by muse, mutect2
- PNMA3 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 55/258 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs782049640, COSV64722539; called by muse, mutect2, varscan2
- POFUT2 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 75/315 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1400515450; called by muse, mutect2, varscan2
- POLR3D | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 10/183 reads (5%) | catalogued as rs1377149580, COSV60570436; called by muse, mutect2
- PPCDC | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs145355117, COSV100738781; called by muse, mutect2, varscan2
- PRDX2 | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as rs566102951; called by muse, mutect2, varscan2
- PROM1 | c.2420C>T p.P807L | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564113318; called by muse, mutect2, varscan2
- PRR14L | c.613A>G p.N205D | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.03); catalogued as rs951204950; called by muse, mutect2, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 46/177 reads (26%) | catalogued as rs781858060; called by mutect2, varscan2
- PTCH1 | c.2149G>A p.D717N | Missense Mutation (SNP) | VAF 141/512 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.146); catalogued as rs1311707136, COSV59471961; called by muse, mutect2, varscan2
- PTPRS | c.3072del p.V1025Sfs*18 | Frame Shift Del (DEL) | VAF 37/160 reads (23%) | catalogued as rs756013055, COSV53629833; called by mutect2, pindel, varscan2
- PTPRT | c.3224del p.P1075Rfs*6 | Frame Shift Del (DEL) | VAF 29/104 reads (28%) | catalogued as rs1568940954, COSV62005004; called by mutect2, pindel, varscan2
- PTPRU | c.1670T>G p.L557R | Missense Mutation (SNP) | VAF 22/640 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60535710; called by muse, mutect2
- PTX4 | c.1132G>A p.V378M (on ENST00000447419 / NM_001328608.2; = p.V373M on NM_001013658.1) | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.679); catalogued as rs774104130, COSV53520461; called by muse, mutect2, varscan2
- RAC1 | c.247T>C p.S83P | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV100640973, COSV61821556; called by muse, mutect2
- RALGAPB | c.3287G>A p.C1096Y | Missense Mutation (SNP) | VAF 27/386 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs762407607, COSV53444062; called by muse, mutect2
- RAPGEF5 | c.647del p.K216Rfs*22 (on ENST00000401957 / NM_001367602.2; = p.K519Rfs*22 on NM_012294.5) | Frame Shift Del (DEL) | VAF 55/197 reads (28%) | catalogued as rs770990761; called by mutect2, pindel, varscan2
- RBCK1 | c.1189G>A p.V397I (on ENST00000356286 / NM_031229.4; = p.V355I on NM_006462.6) | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs538961301, COSV62292178; ClinVar: uncertain significance; called by muse, mutect2
- RBM33 | c.97_99del p.R33del | In Frame Del (DEL) | VAF 57/225 reads (25%) | catalogued as rs754543828; called by pindel, varscan2
- RBM47 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs1047835662, COSV55931130; called by muse, mutect2, varscan2
- RFX2 | c.1134+7G>A | Splice Region (SNP) | VAF 12/284 reads (4%) | catalogued as rs956424618; called by muse, mutect2
- RGR | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 63/228 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs142050467, COSV63894665; called by muse, mutect2, varscan2
- RHPN1 | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs776053563, COSV100000330; called by muse, mutect2, varscan2
- RIMBP2 | c.1946C>T p.S649L | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.557); catalogued as rs759748598, COSV55467868, COSV55480427; called by muse, mutect2, varscan2
- RIMS2 | c.3188C>T p.S1063L (on ENST00000666250 / NM_001348490.2; = p.S871L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); catalogued as rs1381385320; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 62/240 reads (26%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- RSF1 | c.3481C>T p.R1161C | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57837503; called by muse, mutect2, varscan2
- SASS6 | c.170del p.L57Yfs*14 | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | catalogued as rs763290832; called by mutect2, varscan2
- SCML4 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.719); catalogued as rs773253589, COSV64637581; called by muse, mutect2, varscan2
- SCN7A | c.233del p.N78Ifs*4 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs764500272; called by mutect2, varscan2
- SDK1 | c.6569G>A p.S2190N | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.99); catalogued as rs756322815; called by muse, mutect2, varscan2
- SEC16A | c.4291G>A p.A1431T | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.06); catalogued as COSV51540906; called by muse, mutect2, varscan2
- SEC24C | c.1375dup p.Q459Pfs*17 | Frame Shift Ins (INS) | VAF 20/88 reads (23%) | catalogued as rs764652839; called by mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 92/170 reads (54%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEL1L2 | c.1003A>G p.N335D | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs762623161; called by muse, mutect2, varscan2
- SEMA5B | c.3371C>T p.T1124M | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as rs369693926; called by muse, mutect2, varscan2
- SEPTIN8 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as rs766234155; called by muse, mutect2, varscan2
- SERPINE3 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs574559050, COSV68544910; called by muse, mutect2, varscan2
- SGCA | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 80/327 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769778891, COSV56251217; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH3BP4 | c.2323G>A p.A775T | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.546); catalogued as rs1441652876, COSV60646439; called by muse, mutect2, varscan2
- SHANK1 | c.2093C>T p.A698V | Missense Mutation (SNP) | VAF 64/215 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs759737751, COSV53256998, COSV53264713; called by muse, mutect2, varscan2
- SHC1 | c.92del p.P31Rfs*35 | Frame Shift Del (DEL) | VAF 24/104 reads (23%) | catalogued as rs752843778; called by mutect2, pindel, varscan2
- SHC2 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.835); catalogued as rs774445756; called by muse, mutect2, varscan2
- SLC45A1 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.921); catalogued as rs757409091, COSV57098159; called by muse, mutect2, varscan2
- SLC6A12 | c.1663G>A p.V555I | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1286413138, COSV62885884; called by muse, mutect2, varscan2
- SLC6A2 | c.408C>T p.G136= | Splice Region (SNP) | VAF 8/200 reads (4%) | catalogued as COSV54920810; called by muse, mutect2
- SLC7A3 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 99/321 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs374563735, COSV53226623; called by muse, mutect2, varscan2
- SLC9A5 | c.1123C>T p.R375* | Nonsense Mutation (SNP) | VAF 52/208 reads (25%) | catalogued as rs775235682; called by muse, varscan2
- SLIT3 | c.3370G>A p.D1124N | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs776647505, COSV60634131; called by muse, mutect2
- SLITRK4 | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs997536820, COSV100567547, COSV62023284; called by muse, mutect2, varscan2
- SMAD6 | c.1076A>G p.D359G | Missense Mutation (SNP) | VAF 16/572 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99994183; called by muse, mutect2
- SMARCA4 | c.3953G>A p.R1318H | Missense Mutation (SNP) | VAF 26/514 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60812612; called by muse, mutect2
- SNRPN | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs886051020, COSV57600254; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SOHLH1 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 119/602 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs572151479, COSV53684234; called by muse, mutect2, varscan2
- SP6 | c.1080del p.G362Afs*37 | Frame Shift Del (DEL) | VAF 28/130 reads (22%) | catalogued as rs768829645, COSV60618694; called by mutect2, pindel
- SPATA22 | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as rs1325336877, COSV52152814; called by muse, mutect2, varscan2
- SPEG | c.6697del p.Q2233Rfs*6 | Frame Shift Del (DEL) | VAF 70/252 reads (28%) | catalogued as rs752907815; called by mutect2, varscan2
- SPOCD1 | c.3282del p.R1095Gfs*32 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | catalogued as rs1455579753; called by mutect2, pindel, varscan2
- SPTBN1 | c.4654G>A p.V1552I | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs551497805; called by muse, mutect2, varscan2
- SPTBN5 | c.6500C>T p.A2167V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs776487294; called by muse, mutect2
- SRMS | c.254del p.G85Afs*119 | Frame Shift Del (DEL) | VAF 30/145 reads (21%) | catalogued as COSV53922142; called by mutect2, pindel, varscan2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 78/272 reads (29%) | catalogued as rs752994755; called by mutect2, varscan2
- STAP2 | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1000539835, COSV74070973, COSV74071012; called by muse, mutect2, varscan2
- STK36 | c.3706C>T p.R1236W | Missense Mutation (SNP) | VAF 96/371 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.928); catalogued as rs776619847, COSV99831582; called by muse, mutect2, varscan2
- STOML1 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV57552124; called by muse, mutect2, varscan2
- STPG1 | c.150del p.G51Dfs*90 | Frame Shift Del (DEL) | VAF 29/100 reads (29%) | catalogued as rs1210126972; called by mutect2, varscan2
- SUPT16H | c.1174A>G p.K392E | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as rs779648070, COSV53522481, COSV53522493; called by muse, mutect2, varscan2
- SYNDIG1 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 93/370 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs759097945, COSV65237263; called by muse, mutect2, varscan2
- SYT10 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 73/287 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99951014; called by muse, mutect2, varscan2
- SZT2 | c.8866G>A p.G2956S (on ENST00000634258 / NM_001365999.1; = p.G2899S on NM_015284.4) | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.895); catalogued as rs201072050; called by muse, mutect2, varscan2
- TADA3 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 25/261 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1383875900, COSV57333111; called by muse, mutect2, varscan2
- TAS1R2 | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 230/814 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs755734470, COSV64744546; called by muse, varscan2
- TAS1R2 | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 254/836 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as rs778839734, COSV64744095; called by muse, varscan2
- TCF3 | c.1573del p.R525Gfs*76 | Frame Shift Del (DEL) | VAF 32/76 reads (42%) | catalogued as COSV53646783, COSV53650404; called by mutect2, varscan2
- TECTA | c.4276G>A p.G1426S | Missense Mutation (SNP) | VAF 88/285 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143250687; called by muse, mutect2, varscan2
- TEKT5 | c.1120A>G p.I374V | Missense Mutation (SNP) | VAF 70/240 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs758867143; called by muse, mutect2, varscan2
- TENM3 | c.2203G>T p.G735* | Nonsense Mutation (SNP) | VAF 31/71 reads (44%) | catalogued as COSV101305211; called by muse, mutect2, varscan2
- TEP1 | c.5566dup p.V1856Gfs*85 | Frame Shift Ins (INS) | VAF 60/288 reads (21%) | catalogued as rs746695887; called by mutect2, varscan2
- TEX13C | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 50/220 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1029279345; called by muse, mutect2, varscan2
- TGM4 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.051); catalogued as rs367997401; called by muse, mutect2, varscan2
- THSD7B | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 71/298 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.278); catalogued as COSV55683996; called by muse, mutect2, varscan2
- TJP3 | c.1433_1435del p.F478del | In Frame Del (DEL) | VAF 9/74 reads (12%) | catalogued as rs1237422669; called by mutect2, varscan2
- TLE6 | c.1483C>T p.H495Y (on ENST00000246112 / NM_001143986.2; = p.H372Y on NM_024760.3) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs533155876; called by muse, mutect2, varscan2
- TLN2 | c.3443C>T p.A1148V | Missense Mutation (SNP) | VAF 148/474 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as rs768697506, COSV60894731; called by muse, mutect2, varscan2
- TMEM198 | c.467del p.G156Afs*23 | Frame Shift Del (DEL) | VAF 13/73 reads (18%) | catalogued as rs1310164939, COSV54719891; called by mutect2, pindel, varscan2
- TMEM200B | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.368); catalogued as COSV58041213; called by muse, mutect2
- TMEM94 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.232); catalogued as rs757135690, COSV100051116; called by muse, mutect2, varscan2
- TMPRSS12 | c.886C>T p.R296* | Nonsense Mutation (SNP) | VAF 63/247 reads (26%) | catalogued as rs199758447; called by muse, mutect2, varscan2
- TNK2 | c.1955G>A p.S652N | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.632); catalogued as rs1464219947; called by muse, varscan2
- TNRC6A | c.3196dup p.E1066Gfs*11 | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | catalogued as rs1431797734; called by mutect2, pindel
- TRAPPC6B | c.193A>G p.M65V | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs752969156; called by muse, mutect2, varscan2
- TRIM51 | c.430del p.M144Cfs*15 | Frame Shift Del (DEL) | VAF 28/88 reads (32%) | catalogued as rs763121810; called by mutect2, varscan2
- TRIO | c.7945G>A p.G2649S | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.177); catalogued as rs200240991, COSV59990432; called by muse, mutect2, varscan2
- TRPV6 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1466949494; called by muse, mutect2, varscan2
- TSHZ3 | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV53676148; called by mutect2, varscan2
- TTC3 | c.5495G>A p.R1832H | Missense Mutation (SNP) | VAF 76/275 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1304356285; called by muse, mutect2, varscan2
- TTF1 | c.1007del p.K336Rfs*87 | Frame Shift Del (DEL) | VAF 66/217 reads (30%) | catalogued as rs772401251; called by mutect2, varscan2
- TTF2 | c.3409G>A p.A1137T | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101037344; called by muse, mutect2, varscan2
- TXK | c.69G>A p.K23= | Splice Region (SNP) | VAF 52/174 reads (30%) | catalogued as COSV51913641; called by muse, mutect2, varscan2
- UBE2S | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 80/358 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs762293175, COSV52740687; called by muse, mutect2, varscan2
- UBE3A | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 76/280 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs587783101, COSV51669374; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBN1 | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); catalogued as rs138346663; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3996del p.I1333Sfs*20 | Frame Shift Del (DEL) | VAF 63/174 reads (36%) | catalogued as COSV51954201; called by mutect2, pindel, varscan2
- UNC79 | c.4478del p.K1493Sfs*12 (on ENST00000393151 / NM_001346218.2; = p.K1316Sfs*12 on NM_020818.5) | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | catalogued as rs760213136; called by mutect2, varscan2
- UNC80 | c.8117G>A p.R2706Q | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1169935090; called by muse, mutect2, varscan2
- UPF2 | c.2764G>A p.V922I | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.218); catalogued as rs746024154; called by muse, mutect2, varscan2
- USP10 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1419787636; called by muse, mutect2, varscan2
- USP43 | c.3066dup p.V1023Rfs*53 | Frame Shift Ins (INS) | VAF 43/161 reads (27%) | catalogued as rs755601992; called by mutect2, pindel, varscan2
- USP48 | c.1102A>G p.K368E | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV57608128; called by muse, mutect2, varscan2
- VAC14 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs752683960, COSV55752608; called by muse, mutect2, varscan2
- VPS13C | c.3383G>A p.R1128Q (on ENST00000644861 / NM_020821.3; = p.R1085Q on NM_017684.5) | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs756602401, COSV51426410; called by muse, mutect2
- VPS28 | c.658C>T p.H220Y | Missense Mutation (SNP) | VAF 100/450 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV52871282; called by muse, mutect2, varscan2
- VPS37A | c.848dup p.N283Kfs*18 | Frame Shift Ins (INS) | VAF 24/125 reads (19%) | catalogued as rs1156515396; called by mutect2, pindel, varscan2
- VWA3B | c.3522-2A>G p.X1174_splice | Splice Site (SNP) | VAF 4/70 reads (6%) | catalogued as rs1182894922; called by muse, mutect2
- WASF3 | c.920del p.P307Rfs*28 | Frame Shift Del (DEL) | VAF 32/112 reads (29%) | catalogued as rs756173793; called by mutect2, varscan2
- WDFY3 | c.9076G>A p.V3026I | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs777008947, COSV55694347; called by muse, mutect2, varscan2
- WDR81 | c.4621G>A p.E1541K (on ENST00000409644 / NM_001163809.2; = p.E490K on NM_152348.4) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.207); catalogued as rs778513741; called by muse, mutect2, varscan2
- WDR90 | c.4664G>A p.C1555Y | Missense Mutation (SNP) | VAF 77/270 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs780863972; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 48/146 reads (33%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WSCD1 | c.907del p.R303Gfs*125 | Frame Shift Del (DEL) | VAF 51/197 reads (26%) | catalogued as rs1237564131; called by mutect2, pindel, varscan2
- XKR4 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs755320377, COSV59336197; called by muse, mutect2, varscan2
- XPOT | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.241); catalogued as rs765621181; called by muse, mutect2, varscan2
- XRN1 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs765434787, COSV99377865; called by muse, mutect2, varscan2
- YLPM1 | c.761dup p.G255Wfs*3 | Frame Shift Ins (INS) | VAF 37/178 reads (21%) | catalogued as rs760065689; called by mutect2, varscan2
- ZAN | c.4685G>A p.G1562D | Missense Mutation (SNP) | VAF 102/361 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1487764854; called by muse, mutect2, varscan2
- ZBTB18 | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs368207817, COSV100699982, COSV100700129; called by muse, mutect2, varscan2
- ZBTB22 | c.1049del p.G350Efs*9 | Frame Shift Del (DEL) | VAF 16/83 reads (19%) | catalogued as rs746078084; called by mutect2, pindel, varscan2
- ZBTB39 | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 56/238 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1392152529; called by muse, mutect2, varscan2
- ZBTB46 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs754383826, COSV55513997; called by muse, mutect2, varscan2
- ZC3H18 | c.942del p.A315Qfs*18 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | catalogued as COSV56322579; called by mutect2, pindel, varscan2
- ZCRB1 | c.410dup p.K138Efs*7 | Frame Shift Ins (INS) | VAF 32/122 reads (26%) | catalogued as rs746839691; called by mutect2, varscan2
- ZDHHC2 | c.809A>G p.Q270R | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV50497529; called by muse, mutect2, varscan2
- ZFP57 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 76/255 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs1362771214; called by muse, mutect2, varscan2
- ZFPL1 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 114/469 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs751924582, COSV99298079; called by muse, mutect2, varscan2
- ZKSCAN5 | c.2072del p.N691Mfs*12 | Frame Shift Del (DEL) | VAF 86/322 reads (27%) | catalogued as rs556762260; called by mutect2, varscan2
- ZNF20 | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 15/239 reads (6%) | catalogued as rs777207590, COSV61998789; called by muse, mutect2
- ZNF292 | c.6145del p.S2049Vfs*11 | Frame Shift Del (DEL) | VAF 36/132 reads (27%) | catalogued as rs764995318; called by mutect2, varscan2
- ZNF347 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 74/278 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as COSV61970840; called by muse, mutect2, varscan2
- ZNF442 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); catalogued as rs200033674; called by muse, mutect2, varscan2
- ZNF462 | c.4697C>T p.T1566M | Missense Mutation (SNP) | VAF 78/255 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); catalogued as rs773795172, COSV52951433; called by muse, mutect2, varscan2
- ZNF592 | c.2731G>A p.V911I | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.502); catalogued as rs1211858750; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF646 | c.4744G>A p.A1582T | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs746511789, COSV54925166; called by muse, mutect2
- ZNF681 | c.1031G>C p.G344A | Missense Mutation (SNP) | VAF 81/294 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs939991447; called by muse, mutect2, varscan2
- ZNF76 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 82/246 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs754015499; called by muse, mutect2, varscan2
- ZNF845 | c.2438G>A p.R813H | Missense Mutation (SNP) | VAF 86/280 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.879); catalogued as rs192400972, COSV72004153; called by muse, mutect2, varscan2
- ZNF853 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as rs779484251; called by muse, mutect2, varscan2
- AARD | c.45G>T p.Q15H | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.089); called by muse, mutect2
- ABCG8 | c.1730T>C p.M577T | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- AC011005.1 | c.115A>G p.K39E | Missense Mutation (SNP) | VAF 111/454 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- AC126283.2 | c.1378C>A p.L460I | Missense Mutation (SNP) | VAF 85/281 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- ACOT7 | c.529C>T p.P177S (on ENST00000377855 / NM_181864.3; = p.P167S on NM_007274.4) | Missense Mutation (SNP) | VAF 53/245 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACR | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ACSM3 | c.34C>T p.H12Y | Missense Mutation (SNP) | VAF 70/229 reads (31%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ADGRF5 | c.2634G>T p.W878C | Missense Mutation (SNP) | VAF 9/215 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); called by muse, mutect2
- AGBL2 | c.952T>C p.Y318H | Missense Mutation (SNP) | VAF 65/259 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AGGF1 | c.2042del p.N681Tfs*29 | Frame Shift Del (DEL) | VAF 103/416 reads (25%) | called by mutect2, varscan2
- AKNAD1 | c.818del p.N273Ifs*3 | Frame Shift Del (DEL) | VAF 26/94 reads (28%) | called by mutect2, pindel, varscan2
- AL592490.1 | c.347del p.P116Lfs*11 | Frame Shift Del (DEL) | VAF 32/139 reads (23%) | called by mutect2, pindel, varscan2
- ALK | c.3349A>G p.T1117A | Missense Mutation (SNP) | VAF 167/535 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ANK1 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 26/402 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2
- ANKMY1 | c.707G>A p.S236N | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- APOF | c.944_945del p.Y315* | Frame Shift Del (DEL) | VAF 31/125 reads (25%) | called by mutect2, pindel, varscan2
- AQR | c.1012C>T p.Q338* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- ARAP1 | c.2945C>T p.T982M (on ENST00000393609 / NM_001040118.2; = p.T737M on NM_015242.4) | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARID1A | c.3216del p.K1072Nfs*21 | Frame Shift Del (DEL) | VAF 49/194 reads (25%) | called by mutect2, pindel, varscan2
- ARID1A | c.4220del p.P1407Qfs*74 | Frame Shift Del (DEL) | VAF 41/137 reads (30%) | called by mutect2, pindel, varscan2
- ARID1B | c.3317dup p.N1106Kfs*6 | Frame Shift Ins (INS) | VAF 12/70 reads (17%) | called by mutect2, pindel, varscan2
- ASAP2 | c.2357del p.P786Rfs*25 | Frame Shift Del (DEL) | VAF 23/105 reads (22%) | called by mutect2, pindel, varscan2
- ASH1L | c.7301A>T p.E2434V (on ENST00000368346 / NM_001366177.2; = p.E2429V on NM_018489.3) | Missense Mutation (SNP) | VAF 65/220 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ASMTL | c.1344T>G p.N448K | Missense Mutation (SNP) | VAF 115/391 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ATRIP | c.760A>C p.S254R | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- AUTS2 | c.2846T>A p.V949E | Missense Mutation (SNP) | VAF 25/360 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.092); called by muse, mutect2
- BHLHE22 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.088); called by muse, varscan2
- BICC1 | c.1696del p.I566Sfs*5 | Frame Shift Del (DEL) | VAF 22/107 reads (21%) | called by mutect2, pindel, varscan2
- BRPF3 | c.1688G>A p.R563Q | Missense Mutation (SNP) | VAF 58/229 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- C2CD2L | c.286A>G p.K96E | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- C2CD4D | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- C5 | c.2690C>T p.T897I | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2
- CACNA1E | c.3532A>G p.T1178A | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CACNA1H | c.475G>T p.G159W | Missense Mutation (SNP) | VAF 74/252 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAD | c.1621-11_1623del p.X541_splice | Splice Site (DEL) | VAF 78/238 reads (33%) | called by mutect2, pindel, varscan2
- CALD1 | c.1886A>G p.D629G (on ENST00000361675 / NM_033138.4; = p.D374G on NM_004342.7) | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- CAMTA1 | c.4033G>T p.G1345* | Nonsense Mutation (SNP) | VAF 83/299 reads (28%) | called by muse, mutect2, varscan2
- CAP1 | c.571A>G p.T191A | Missense Mutation (SNP) | VAF 62/235 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.119); called by muse, varscan2
- CASC3 | c.1862_1865del p.Y621Ffs*7 | Frame Shift Del (DEL) | VAF 122/403 reads (30%) | called by pindel, varscan2
- CASZ1 | c.5203G>A p.A1735T | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); called by muse, mutect2
- CASZ1 | c.1834T>C p.C612R | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CC2D1A | c.1220del p.P407Qfs*27 | Frame Shift Del (DEL) | VAF 16/125 reads (13%) | called by mutect2, pindel, varscan2
- CC2D1B | c.1019-2A>G p.X340_splice | Splice Site (SNP) | VAF 43/114 reads (38%) | called by muse, mutect2, varscan2
- CCDC88B | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 90/345 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CCDC92 | c.316T>A p.L106M | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCM2 | c.1018C>T p.Q340* | Nonsense Mutation (SNP) | VAF 24/506 reads (5%) | called by muse, mutect2
- CCNE2 | c.-26-6del | Splice Region (DEL) | VAF 10/80 reads (13%) | called by mutect2, pindel, varscan2
- CCRL2 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CDC42BPB | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEMIP | c.1060del p.I354Yfs*54 | Frame Shift Del (DEL) | VAF 105/456 reads (23%) | called by mutect2, pindel, varscan2
- CENPB | c.769C>A p.L257M | Missense Mutation (SNP) | VAF 67/193 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP162 | c.2761del p.I921Ffs*15 | Frame Shift Del (DEL) | VAF 43/147 reads (29%) | called by mutect2, pindel, varscan2
- CEPT1 | c.553dup p.C185Lfs*28 | Frame Shift Ins (INS) | VAF 45/203 reads (22%) | called by mutect2, varscan2
- CLCA4 | c.426del p.K142Nfs*96 | Frame Shift Del (DEL) | VAF 21/110 reads (19%) | called by mutect2, pindel, varscan2
- CLCN3 | c.931del p.R311Gfs*14 | Frame Shift Del (DEL) | VAF 23/84 reads (27%) | called by mutect2, pindel, varscan2
- CLDN18 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.515); called by muse, mutect2
- CLEC18A | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 220/854 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, varscan2
- CLEC9A | c.337T>C p.C113R | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNTN2 | c.2172del p.G725Efs*105 | Frame Shift Del (DEL) | VAF 73/290 reads (25%) | called by mutect2, pindel, varscan2
- COMMD5 | c.305C>T p.T102I | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2
- CPSF7 | c.1028G>A p.R343Q (on ENST00000394888 / NM_001136040.4; = p.R386Q on NM_024811.4) | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CPSF7 | c.734del p.P245Hfs*67 (on ENST00000394888 / NM_001136040.4; = p.P288Hfs*67 on NM_024811.4) | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
- CRB3 | c.130A>G p.T44A | Missense Mutation (SNP) | VAF 87/284 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- CREBBP | c.4268del p.P1423Lfs*36 | Frame Shift Del (DEL) | VAF 68/238 reads (29%) | called by mutect2, varscan2
- CRP | c.401G>A p.R134K | Missense Mutation (SNP) | VAF 110/398 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CRYBG2 | c.1177_1178del p.K393Gfs*52 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by pindel, varscan2
- CSTF2T | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- CTSV | c.533G>A p.C178Y | Missense Mutation (SNP) | VAF 101/396 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CUL5 | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.142); called by muse, mutect2
- CUX1 | c.3325_3326del p.S1109Rfs*54 | Frame Shift Del (DEL) | VAF 60/284 reads (21%) | called by pindel, varscan2
- CUX2 | c.3203G>A p.R1068Q | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- CYP26B1 | c.850C>T p.Q284* | Nonsense Mutation (SNP) | VAF 129/456 reads (28%) | called by muse, mutect2, varscan2
- CYP27B1 | c.534del p.P179Rfs*56 | Frame Shift Del (DEL) | VAF 88/355 reads (25%) | called by mutect2, pindel, varscan2
- CYTH2 | c.387del p.F129Lfs*35 | Frame Shift Del (DEL) | VAF 77/293 reads (26%) | called by mutect2, pindel, varscan2
- DCDC1 | c.5284C>A p.P1762T (on ENST00000597505 / NM_001367979.1; = p.P869T on NM_020869.3) | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, varscan2
- DENND2B | c.293G>T p.S98I | Missense Mutation (SNP) | VAF 91/321 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- DGUOK | c.524_525del p.F175Sfs*40 | Frame Shift Del (DEL) | VAF 68/273 reads (25%) | called by mutect2, pindel, varscan2
- DLEC1 | c.823A>G p.T275A | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.099); called by muse, mutect2
- DLGAP4 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2
- DLGAP5 | c.741A>C p.R247S | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- DNAH7 | c.9646del p.S3216Lfs*5 | Frame Shift Del (DEL) | VAF 65/277 reads (23%) | called by mutect2, pindel, varscan2
- DOCK4 | c.3136T>C p.C1046R | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DOCK7 | c.2629G>A p.A877T | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- DPYSL3 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 86/385 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- DSPP | c.1952G>A p.S651N | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- EDN3 | c.262del p.A88Pfs*121 (on ENST00000337938 / NM_001302455.2; = p.A88Pfs*110 on NM_207032.3) | Frame Shift Del (DEL) | VAF 80/311 reads (26%) | called by mutect2, pindel, varscan2
- EFS | c.389T>C p.I130T | Missense Mutation (SNP) | VAF 94/306 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- EGFR | c.3242G>A p.S1081N | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELK1 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 72/248 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ELMO1 | c.212del p.N71Mfs*7 | Frame Shift Del (DEL) | VAF 48/164 reads (29%) | called by mutect2, pindel, varscan2
- EML4 | c.353del p.K118Rfs*55 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | called by mutect2, pindel, varscan2
- EML4 | c.1353+1dup | Frame Shift Ins (INS) | VAF 18/85 reads (21%) | called by mutect2, pindel, varscan2
- ENDOV | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPX | c.820C>A p.R274S | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERCC6L | c.614T>C p.L205S | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAM102B | c.510_512del p.E170del | In Frame Del (DEL) | VAF 20/106 reads (19%) | called by pindel, varscan2
- FAM135A | c.941dup p.L314Ffs*36 (on ENST00000370479 / NM_001351599.1; = p.L297Ffs*36 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 19/199 reads (10%) | called by mutect2, pindel
- FAM184B | c.2972A>G p.D991G | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FAM71D | c.961del p.S321Vfs*5 | Frame Shift Del (DEL) | VAF 41/155 reads (26%) | called by mutect2, pindel, varscan2
- FBXO15 | c.696del p.K232Nfs*5 | Frame Shift Del (DEL) | VAF 59/273 reads (22%) | called by mutect2, pindel, varscan2
- FCRL6 | c.57G>A p.W19* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2
- FGGY | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- FN1 | c.6271A>G p.R2091G (on ENST00000359671 / NM_001365524.2; = p.R2001G on NM_212476.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.428); called by muse, mutect2
- FRAT1 | c.697del p.Q233Nfs*88 | Frame Shift Del (DEL) | VAF 98/376 reads (26%) | called by mutect2, pindel, varscan2
- FSCN1 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- FSIP2 | c.16728del p.D5579Mfs*10 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- GABBR2 | c.1808del p.G603Afs*4 | Frame Shift Del (DEL) | VAF 21/81 reads (26%) | called by mutect2, pindel, varscan2
- GCNT4 | c.1108A>G p.K370E | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GLDC | c.2131A>G p.S711G | Missense Mutation (SNP) | VAF 11/287 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- GMFB | c.215G>A p.S72N | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); called by muse, mutect2
- GNAS | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 88/317 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- GNE | c.1957G>A p.V653M (on ENST00000396594 / NM_001128227.3; = p.V622M on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/540 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.584); called by mutect2, varscan2
- GOLGA4 | c.1276del p.T426Qfs*8 | Frame Shift Del (DEL) | VAF 33/146 reads (23%) | called by mutect2, pindel, varscan2
- GPR42 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 22/460 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.176); called by muse, mutect2
- GRAMD1C | c.1044del p.S349Vfs*14 | Frame Shift Del (DEL) | VAF 48/220 reads (22%) | called by mutect2, pindel, varscan2
- GRM6 | c.2119C>A p.L707M | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- GUCY2F | c.1270G>A p.V424M | Missense Mutation (SNP) | VAF 58/283 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- H2AZ2 | c.187A>G p.T63A | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- H4C3 | c.241A>G p.T81A | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- HACD2 | c.526T>A p.Y176N | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HAUS5 | c.1603G>T p.D535Y | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HCRTR1 | c.560G>A p.S187N | Missense Mutation (SNP) | VAF 85/298 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HERC1 | c.6709dup p.M2237Nfs*9 | Frame Shift Ins (INS) | VAF 56/200 reads (28%) | called by mutect2, varscan2
- HES5 | c.40A>G p.K14E | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); called by muse, mutect2
- HIVEP3 | c.3866del p.P1289Lfs*95 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- HLA-A | c.695_697del p.F232del | In Frame Del (DEL) | VAF 34/158 reads (22%) | called by mutect2, varscan2
- HPD | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 16/422 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HPS4 | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 96/372 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- HSFX3 | c.455G>A p.S152N | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HSPG2 | c.1652A>T p.K551M | Missense Mutation (SNP) | VAF 113/394 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- HUWE1 | c.10205G>A p.R3402Q | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2
- HUWE1 | c.10064G>T p.R3355L | Missense Mutation (SNP) | VAF 66/243 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- IFIT1 | c.313T>C p.Y105H | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- IFIT1B | c.713del p.K238Sfs*7 | Frame Shift Del (DEL) | VAF 34/152 reads (22%) | called by mutect2, pindel, varscan2
- IGSF9B | c.439del p.Q147Sfs*13 | Frame Shift Del (DEL) | VAF 32/152 reads (21%) | called by mutect2, pindel, varscan2
- IL11 | c.8-3del | Splice Region (DEL) | VAF 9/56 reads (16%) | called by mutect2, pindel, varscan2
- INPP5D | c.2765G>T p.G922V (on ENST00000445964 / NM_001017915.3; = p.G921V on NM_005541.5) | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- INTS1 | c.2081T>C p.L694P | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- INVS | c.1629G>A p.M543I | Missense Mutation (SNP) | VAF 104/392 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- IPO4 | c.2201G>A p.S734N | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IPO9 | c.*3del | Frame Shift Del (DEL) | VAF 88/334 reads (26%) | called by mutect2, varscan2
- ITGA8 | c.2983-2A>G p.X995_splice | Splice Site (SNP) | VAF 12/181 reads (7%) | called by muse, mutect2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 64/138 reads (46%) | called by mutect2, varscan2
- JMJD1C | c.6251C>T p.A2084V | Missense Mutation (SNP) | VAF 10/347 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- JPT2 | c.197del p.X66_splice | Splice Site (DEL) | VAF 35/125 reads (28%) | called by mutect2, pindel, varscan2
- KATNIP | c.4040G>T p.R1347L | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNH8 | c.2111dup p.R705Afs*9 | Frame Shift Ins (INS) | VAF 43/159 reads (27%) | called by mutect2, pindel, varscan2
- KIAA0100 | c.3352C>T p.P1118S | Missense Mutation (SNP) | VAF 71/253 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA0825 | c.2301del p.F767Lfs*27 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | called by mutect2, pindel, varscan2
- KIF13B | c.5183G>A p.G1728D | Missense Mutation (SNP) | VAF 19/640 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIF1A | c.353T>C p.I118T | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIF3B | c.1681_1683del p.E561del | In Frame Del (DEL) | VAF 70/266 reads (26%) | called by pindel, varscan2
- KLF17 | c.484G>C p.A162P | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2
- KLK14 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 73/275 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2A | c.173del p.P58Rfs*92 | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | called by mutect2, pindel, varscan2
- LDB1 | c.1138C>T p.P380S (on ENST00000425280 / NM_001321612.2; = p.P346S on NM_003893.5) | Missense Mutation (SNP) | VAF 15/476 reads (3%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2
- LDHAL6B | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 106/454 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.387); called by muse, mutect2
- LMAN1 | c.1149G>A p.Q383= | Splice Region (SNP) | VAF 86/353 reads (24%) | called by muse, mutect2, varscan2
- LMBR1L | c.1239G>A p.L413= | Splice Region (SNP) | VAF 86/236 reads (36%) | called by muse, mutect2, varscan2
- LNX1 | c.1052T>C p.L351P (on ENST00000263925 / NM_001126328.3; = p.L255P on NM_032622.2) | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRCH3 | c.1631G>A p.S544N | Missense Mutation (SNP) | VAF 49/216 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- LRRIQ1 | c.1755dup p.V586Sfs*15 | Frame Shift Ins (INS) | VAF 18/69 reads (26%) | called by mutect2, pindel, varscan2
- MAN2C1 | c.761A>G p.H254R | Missense Mutation (SNP) | VAF 40/417 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); called by muse, mutect2
- MAP3K11 | c.1841del p.P614Rfs*27 | Frame Shift Del (DEL) | VAF 124/408 reads (30%) | called by mutect2, varscan2
- MAP3K13 | c.794G>A p.S265N | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.27); called by muse, mutect2
- MAPK8IP1 | c.1928dup p.N643Kfs*35 | Frame Shift Ins (INS) | VAF 117/494 reads (24%) | called by mutect2, pindel, varscan2
- MCRS1 | c.1295_1296del p.V432Gfs*23 | Frame Shift Del (DEL) | VAF 46/197 reads (23%) | called by pindel, varscan2
- MED14 | c.908T>G p.L303R | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- MEGF8 | c.25A>G p.M9V | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- MEPCE | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 12/297 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- MFSD4A | c.1099A>G p.I367V | Missense Mutation (SNP) | VAF 69/236 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- MGST3 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 13/393 reads (3%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.58); called by muse, mutect2
- MLH1 | c.1844_1845insCGAAGAA p.K616Efs*7 | Frame Shift Ins (INS) | VAF 83/339 reads (24%) | called by mutect2, pindel, varscan2
- MLPH | c.235del p.R79Gfs*35 | Frame Shift Del (DEL) | VAF 112/443 reads (25%) | called by mutect2, pindel, varscan2
- MMP2 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 191/676 reads (28%) | called by muse, mutect2, varscan2
- MPHOSPH8 | c.1265G>T p.R422M | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- MROH7 | c.1887G>T p.E629D | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- MRPS2 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 90/277 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRS2 | c.1187T>C p.L396P | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYBL1 | c.1259del p.N420Tfs*13 | Frame Shift Del (DEL) | VAF 55/185 reads (30%) | called by mutect2, varscan2
- MYH7 | c.42del p.Y15Tfs*10 | Frame Shift Del (DEL) | VAF 71/317 reads (22%) | called by mutect2, pindel, varscan2
- MYH8 | c.5336G>A p.S1779N | Missense Mutation (SNP) | VAF 30/483 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.417); called by muse, mutect2
- MYO15A | c.7861A>G p.M2621V | Missense Mutation (SNP) | VAF 83/258 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- MYO5A | c.797G>A p.C266Y | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYO6 | c.117+2T>C p.X39_splice | Splice Site (SNP) | VAF 110/402 reads (27%) | called by muse, mutect2, varscan2
- NAA35 | c.1687dup p.T563Nfs*29 | Frame Shift Ins (INS) | VAF 36/144 reads (25%) | called by mutect2, varscan2
- NALCN | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- NAV3 | c.1379del p.K460Sfs*32 | Frame Shift Del (DEL) | VAF 19/115 reads (17%) | called by mutect2, pindel, varscan2
- NCAM1 | c.1059G>A p.K353= | Splice Region (SNP) | VAF 9/148 reads (6%) | called by muse, mutect2
- NCKAP1L | c.695G>A p.S232N | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- NCKAP5 | c.3883G>T p.G1295C | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- NCOA2 | c.722_724del p.E241del | In Frame Del (DEL) | VAF 92/356 reads (26%) | called by pindel, varscan2
- NCSTN | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 143/540 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- NDUFA9 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NEMF | c.1124G>T p.W375L | Missense Mutation (SNP) | VAF 62/298 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEURL3 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 66/283 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- NEXN | c.717del p.E240Nfs*8 | Frame Shift Del (DEL) | VAF 71/204 reads (35%) | called by mutect2, pindel, varscan2
- NFATC4 | c.1010A>G p.Q337R | Missense Mutation (SNP) | VAF 22/257 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.106); called by muse, mutect2
- NFE2L1 | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 69/211 reads (33%) | called by muse, mutect2, varscan2
- NFIA | c.642G>T p.Q214H | Missense Mutation (SNP) | VAF 61/256 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NFIC | c.1367del p.P456Lfs*36 (on ENST00000443272 / NM_001245002.2; = p.P447Lfs*36 on NM_205843.3) | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | called by mutect2, pindel, varscan2
- NFKBIZ | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NIPBL | c.6229A>G p.I2077V | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- NKAPD1 | c.479del p.K160Sfs*20 (on ENST00000280352 / NM_001082970.2; = p.K161Sfs*20 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 46/188 reads (24%) | called by mutect2, varscan2
- NKPD1 | c.357dup p.P120Tfs*39 | Frame Shift Ins (INS) | VAF 8/69 reads (12%) | called by mutect2, pindel, varscan2
- NRBP1 | c.591del p.I198Sfs*6 | Frame Shift Del (DEL) | VAF 45/148 reads (30%) | called by mutect2, pindel, varscan2
- NRBP1 | c.1277C>A p.P426H | Missense Mutation (SNP) | VAF 92/393 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- NUDCD1 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NUMA1 | c.5018G>A p.C1673Y | Missense Mutation (SNP) | VAF 27/359 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NUMB | c.902T>A p.L301* (on ENST00000355058; = p.L290* on NM_003744.5) | Nonsense Mutation (SNP) | VAF 45/162 reads (28%) | called by muse, mutect2, varscan2
- ONECUT3 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- OR10A7 | c.634T>A p.C212S | Missense Mutation (SNP) | VAF 73/390 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR1D5 | c.550C>A p.L184M | Missense Mutation (SNP) | VAF 17/381 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- OR1S1 | c.98A>G p.Q33R | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- OR6T1 | c.23A>G p.Q8R | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0); called by mutect2, varscan2
- OR9K2 | c.883A>G p.K295E (on ENST00000305377; = p.K273E on NM_001005243.1) | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- OSBP | c.83del p.P28Qfs*85 | Frame Shift Del (DEL) | VAF 13/100 reads (13%) | called by mutect2, pindel, varscan2
- OTOGL | c.3081del p.L1028Wfs*16 (on ENST00000547103; = p.L1019Wfs*16 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | called by mutect2, pindel, varscan2
- OTUD7A | c.713G>T p.R238M | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- P2RY8 | c.825C>A p.Y275* | Nonsense Mutation (SNP) | VAF 136/479 reads (28%) | called by muse, mutect2, varscan2
- PALB2 | c.1350T>A p.N450K | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PALD1 | c.290G>A p.G97D | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- PALLD | c.2656C>T p.Q886* (on ENST00000505667 / NM_001166108.2; = p.Q869* on NM_016081.4) | Nonsense Mutation (SNP) | VAF 36/422 reads (9%) | called by muse, mutect2
- PAPPA2 | c.391G>T p.G131W | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- PAPPA2 | c.4441G>T p.E1481* | Nonsense Mutation (SNP) | VAF 25/97 reads (26%) | called by muse, mutect2, varscan2
- PAQR9 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 131/457 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- PAX2 | c.1207del p.R403Gfs*37 (on ENST00000428433 / NM_003987.5; = p.R380Gfs*37 on NM_000278.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 59/326 reads (18%) | called by mutect2, pindel, varscan2
- PCDHGA5 | c.281A>C p.E94A | Missense Mutation (SNP) | VAF 22/395 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.752); called by muse, mutect2
- PCK1 | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 105/339 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCP4L1 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 84/343 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- PCSK5 | c.1756+2T>C p.X586_splice | Splice Site (SNP) | VAF 32/103 reads (31%) | called by muse, mutect2, varscan2
- PDE3B | c.2708C>T p.A903V | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PDIA2 | c.778A>G p.T260A | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.098); called by muse, mutect2
- PER2 | c.3269G>A p.G1090E | Missense Mutation (SNP) | VAF 101/417 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- PER3 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKD2 | c.330G>A p.M110I | Missense Mutation (SNP) | VAF 82/326 reads (25%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.046); called by muse, varscan2
- PKHD1L1 | c.8224C>T p.H2742Y | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLEKHG3 | c.2111T>G p.L704R (on ENST00000394691; = p.L760R on NM_001308147.2) | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLEKHM1 | c.1944del p.E649Rfs*62 | Frame Shift Del (DEL) | VAF 74/260 reads (28%) | called by mutect2, varscan2
- PNPLA7 | c.1847T>C p.M616T | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- POU2F3 | c.1118G>A p.S373N | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); called by muse, mutect2
- PPP1R9A | c.325dup p.T109Nfs*7 | Frame Shift Ins (INS) | VAF 16/168 reads (10%) | called by mutect2, pindel
- PPP6R1 | c.1524del p.L510Wfs*13 | Frame Shift Del (DEL) | VAF 62/312 reads (20%) | called by mutect2, pindel, varscan2
- PRDM2 | c.4417C>T p.H1473Y | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRG4 | c.2072C>A p.T691N | Missense Mutation (SNP) | VAF 85/410 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, varscan2
- PRKCG | c.1063A>G p.M355V | Missense Mutation (SNP) | VAF 41/513 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2
- PRKDC | c.2851G>T p.G951W | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- PRKRIP1 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- PRRT1 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTCH1 | c.3131C>T p.A1044V | Missense Mutation (SNP) | VAF 13/363 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- PTEN | c.270del p.F90Lfs*9 | Frame Shift Del (DEL) | VAF 60/252 reads (24%) | called by mutect2, pindel, varscan2
- PTGDR2 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.097); called by muse, mutect2
- PTPN13 | c.600dup p.R201Sfs*18 | Frame Shift Ins (INS) | VAF 11/64 reads (17%) | called by mutect2, pindel, varscan2
- PYCR2 | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- PYGO2 | c.878del p.P293Rfs*45 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- QPRT | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- QRICH1 | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 20/354 reads (6%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2
- RAE1 | c.1052del p.N351Ifs*12 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | called by mutect2, varscan2
- RALGAPB | c.2759C>G p.A920G | Missense Mutation (SNP) | VAF 63/216 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- RAPGEF2 | c.1973C>T p.T658I | Missense Mutation (SNP) | VAF 16/199 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2
- RASGEF1B | c.903C>A p.N301K | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RB1CC1 | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 55/231 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- RBBP6 | c.4572del p.G1525Efs*37 | Frame Shift Del (DEL) | VAF 27/94 reads (29%) | called by mutect2, pindel, varscan2
- RGPD4 | c.3943dup p.S1315Ffs*5 | Frame Shift Ins (INS) | VAF 88/496 reads (18%) | called by mutect2, pindel, varscan2
- RIF1 | c.1400G>A p.S467N | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- RIN3 | c.1043C>T p.T348I | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- RIN3 | c.2921C>T p.P974L | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.381); called by muse, mutect2
- RLF | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 49/147 reads (33%) | called by muse, mutect2, varscan2
- RMND5A | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- ROCK1 | c.3448del p.I1150Ffs*21 | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | called by mutect2, varscan2
- RP1 | c.3448G>A p.A1150T | Missense Mutation (SNP) | VAF 145/498 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RRS1 | c.140del p.P47Rfs*42 | Frame Shift Del (DEL) | VAF 78/302 reads (26%) | called by mutect2, varscan2
- RUNX2 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 104/443 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); called by muse, varscan2
- RXFP3 | c.327G>A p.M109I | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- RXRA | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 18/357 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); called by muse, mutect2
- SAFB2 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 7/170 reads (4%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); called by muse, mutect2
- SALL3 | c.2684C>T p.A895V | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- SAMD10 | c.187C>A p.L63I | Missense Mutation (SNP) | VAF 116/413 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SAMD4A | c.1900A>G p.M634V | Missense Mutation (SNP) | VAF 85/247 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SETD1A | c.476C>A p.S159Y | Missense Mutation (SNP) | VAF 100/362 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SETD1B | c.22del p.H8Tfs*27 | Frame Shift Del (DEL) | VAF 36/76 reads (47%) | called by mutect2, varscan2
- SLAMF7 | c.995A>G p.E332G | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- SLC15A3 | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 78/316 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SLC25A27 | c.316A>G p.M106V | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.124); called by muse, mutect2
- SLC34A2 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 100/416 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC9A5 | c.1039C>A p.L347I | Missense Mutation (SNP) | VAF 154/532 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- SMPD4 | c.753dup p.T252Dfs*23 | Frame Shift Ins (INS) | VAF 6/29 reads (21%) | called by mutect2, pindel
- SOBP | c.229C>T p.L77F | Missense Mutation (SNP) | VAF 83/353 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SOGA1 | c.4977del p.S1660Afs*18 | Frame Shift Del (DEL) | VAF 29/101 reads (29%) | called by mutect2, pindel, varscan2
- SPTBN5 | c.9890C>T p.A3297V | Missense Mutation (SNP) | VAF 69/203 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- SUV39H1 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 82/309 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- SYMPK | c.1152G>T p.K384N | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.034); called by muse, mutect2
- SYPL1 | c.676G>T p.G226* | Nonsense Mutation (SNP) | VAF 56/200 reads (28%) | called by muse, mutect2, varscan2
- SZT2 | c.2175del p.V726Cfs*41 | Frame Shift Del (DEL) | VAF 26/86 reads (30%) | called by mutect2, pindel
- SZT2 | c.3776del p.P1259Lfs*60 (on ENST00000634258 / NM_001365999.1; = p.P1202Lfs*60 on NM_015284.4) | Frame Shift Del (DEL) | VAF 65/289 reads (22%) | called by mutect2, pindel, varscan2
- TAB1 | c.91T>C p.S31P | Missense Mutation (SNP) | VAF 66/220 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- TAPBP | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.169); called by muse, mutect2
- TAS2R14 | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCERG1 | c.300G>A p.M100I | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TCF4 | c.104del p.N35Mfs*16 | Frame Shift Del (DEL) | VAF 52/260 reads (20%) | called by mutect2, pindel, varscan2
- TCF7 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- TDRP | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- TECPR1 | c.2462T>C p.V821A | Missense Mutation (SNP) | VAF 26/422 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- TENT5B | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 55/164 reads (34%) | called by muse, mutect2, varscan2
- TET3 | c.4501G>A p.A1501T | Missense Mutation (SNP) | VAF 20/227 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- TET3 | c.4851del p.S1618Afs*5 | Frame Shift Del (DEL) | VAF 49/223 reads (22%) | called by mutect2, pindel, varscan2
- TEX10 | c.13del p.R5Efs*10 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | called by mutect2, pindel
- THAP7 | c.185_187del p.Y62del | In Frame Del (DEL) | VAF 52/240 reads (22%) | called by mutect2, pindel, varscan2
- TMEM236 | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 183/639 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- TMEM249 | c.521A>G p.H174R | Missense Mutation (SNP) | VAF 11/217 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TMEM26 | c.805C>A p.L269I | Missense Mutation (SNP) | VAF 100/343 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- TMEM268 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.294); called by muse, mutect2
- TRMT2A | c.1003del p.Q335Rfs*3 | Frame Shift Del (DEL) | VAF 45/208 reads (22%) | called by mutect2, pindel, varscan2
- TRPS1 | c.557dup p.N186Kfs*14 (on ENST00000220888 / NM_001330599.2; = p.N199Kfs*14 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 52/194 reads (27%) | called by mutect2, pindel, varscan2
- TTN | c.37037A>G p.E12346G (on ENST00000591111; = p.E4922G on NM_003319.4) | Missense Mutation (SNP) | VAF 41/158 reads (26%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.26544del p.K8848Nfs*12 (on ENST00000591111; = p.K7921Nfs*12 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 32/169 reads (19%) | called by mutect2, pindel, varscan2
- UBL7 | c.559A>G p.N187D | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); called by muse, mutect2
- UCKL1 | c.1378G>A p.A460T | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- UNK | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 44/190 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); called by muse, varscan2
449 further variants in this file (33 protein-altering or splice-affecting, 272 silent, 144 other) are not listed here.
